Gene-level copy-number profile of tumor specimen ALCH-ABFP-TTP1-A from ALCHEMIST case ALCH-ABFP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.9 years (17,511 days).
Specimen ALCH-ABFP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04f977e9-25ca-4d70-97ce-e92d13769431.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABFP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/5b00a3c0-e735-458f-b779-2e66b6c87919

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 17; copy number 2: 4,892; copy number 3: 8,390; copy number 4: 23,954; copy number 5: 6,138; copy number 6: 9,000; copy number 7: 4,487; copy number 8: 665; copy number 9: 129; copy number 10: 65; copy number 11: 15; copy number 12: 1; copy number 13: 91; copy number 14: 115; copy number 15: 12; copy number 16: 15; copy number 17: 132; copy number 18: 16; copy number 19: 145; copy number 21: 1; copy number 22: 3; copy number 23: 30; copy number 24: 15; copy number 25: 3; copy number 26: 28; copy number 27: 1; copy number 31: 4; copy number 33: 13.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,631,046–39,810,097, 7 genes: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–3): BX664615.2.
- chr10:30,655,489–30,723,740, 2 genes (within-gene range 0–2): SVIL2P, LINC02644.
- chr15:20,379,495–20,520,627, 2 genes: HERC2P3, AC023310.1.
- chr15:75,598,083–75,626,469, 2 genes (within-gene range 0–3): SNUPN, AC105020.3.
- chr18:12,307,669–12,344,320, 1 gene (within-gene range 0–4): TUBB6.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.
- chr22:37,570,248–37,582,616, 2 genes: LGALS2, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 834 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,234,692–6,261,098, 3 genes, copy number 11 (within-gene range 5–11): LINC00337, HES3, GPR153.
- chr5:135,802,985–135,803,075, 1 gene, copy number 9: MIR5692C1.
- chr8:66,667,596–66,860,472, 1 gene, copy number 9 (within-gene range 6–9): C8orf44-SGK3.
- chr8:66,712,734–67,746,378, 19 genes, copy number 9: SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:91,909,738–91,917,918, 2 genes, copy number 9: PRR13P7, MRPS16P1.
- chr8:93,029,751–93,029,839, 1 gene, copy number 11: MIR8084.
- chr8:95,204,456–95,993,103, 8 genes, copy number 13 (within-gene range 8–13): C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P, SRSF3P2, AC012339.1.
- chr8:97,241,742–110,556,518, 225 genes, copy number 9–33 (broad region; genes not listed).
- chr9:12,134–73,865, 5 genes, copy number 15 (within-gene range 2–15): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:65,189,995–65,193,610, 1 gene, copy number 12: BMS1P12.
- chr14:35,538,352–40,390,547, 76 genes, copy number 9–23 (within-gene range 6–23) (broad region; genes not listed).
- chr15:20,531,856–20,549,444, 2 genes, copy number 14: GOLGA6L6, AC023310.3.
- chr15:101,922,042–101,933,350, 2 genes, copy number 10: OR4F4, OR4G2P.
- chr21:8,603,547–8,603,984, 1 gene, copy number 10: RPSAP68.
- chr21:22,209,920–40,847,158, 363 genes, copy number 9–31 (within-gene range 6–31) (broad region; genes not listed).
- chr21:40,736,318–40,754,888, 1 gene, copy number 11: AF064866.1.
- chr21:44,107,373–46,691,226, 123 genes, copy number 9–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
